CCDI case PBCPYI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d66aaf3c-5afa-4e85-a1c7-4cca21df4ca4

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 16.8 years (6,123 days).

Biospecimens (3 samples)
- Sample 0DX4EV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX4F8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX4FQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
